Somatic mutation profile of tumor specimen ALCH-B0EV-TTP1-A (aliquot ALCH-B0EV-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0EV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.9 years (20,780 days).
Specimen ALCH-B0EV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 657eb386-c36d-4df4-9399-6372ff5ad682.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0EV-NB1-A (Blood Derived Normal), aliquot ALCH-B0EV-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a355cb4-8ee9-4328-b55c-dd403bff4632

The open-access MAF lists 975 somatic variants for this specimen: 661 protein-altering or splice-affecting, 189 silent, 125 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 563, Silent 189, Nonsense Mutation 54, Intron 49, RNA 25, 3'UTR 24, Splice Site 15, Frame Shift Del 15, 5'UTR 13, 5'Flank 12, Splice Region 7, Frame Shift Ins 5.

Variants (750 of 975; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 54/172 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 69/276 reads (25%) | hotspot (GDC flag); catalogued as rs121912652, CM900213, COSV52684909, COSV52740428, COSV52828352; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1406C>G p.S469C (on ENST00000373993 / NM_138932.2; = p.S461C on NM_014576.4) | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763691496; called by muse, mutect2, varscan2
- ABCB4 | c.1845C>G p.S615R | Missense Mutation (SNP) | VAF 40/464 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV55941319, COSV99710359; called by muse, mutect2
- ADAMTS16 | c.1217C>G p.P406R | Missense Mutation (SNP) | VAF 157/294 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57009361; called by muse, varscan2
- ADAMTS16 | c.1775G>T p.W592L | Missense Mutation (SNP) | VAF 247/520 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57004908; called by muse, mutect2, varscan2
- ADARB2 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs969896291; called by muse, mutect2
- ADGRG4 | c.1427C>A p.T476K | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV99794205; called by muse, mutect2
- ADGRG4 | c.3014C>A p.S1005* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as COSV54950222; called by mutect2, varscan2
- ADGRL2 | c.1469G>T p.R490L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV54651687; called by muse, mutect2, varscan2
- ADGRL3 | c.3170G>T p.G1057V (on ENST00000506720 / NM_001322402.2; = p.G989V on NM_015236.6) | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.542); catalogued as rs1211112993; called by muse, varscan2
- ADGRV1 | c.12415A>G p.I4139V | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1157655678; called by muse, mutect2, varscan2
- AMER1 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as COSV57668719; called by muse, mutect2, varscan2
- ANKRD24 | c.2785C>A p.L929M | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.95); catalogued as rs1402846479; called by muse, mutect2
- ANKRD30A | c.2729C>G p.P910R (on ENST00000611781; = p.P854R on NM_052997.2) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as COSV100654449; called by muse, mutect2, varscan2
- ANKRD33B | c.859G>T p.V287L | Missense Mutation (SNP) | VAF 34/433 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as rs865834509; called by muse, mutect2
- ANKS6 | c.1798G>T p.V600L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV62051741; called by muse, mutect2, varscan2
- AOAH | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 10/82 reads (12%) | catalogued as COSV51751357; called by muse, varscan2
- ARID1A | c.1741C>T p.Q581* | Nonsense Mutation (SNP) | VAF 28/229 reads (12%) | catalogued as COSV61373650; called by muse, mutect2, varscan2
- ASB15 | c.1378T>A p.W460R | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.531); catalogued as COSV99306941; called by muse, mutect2, varscan2
- BHMT | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 80/382 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.827); catalogued as COSV57156178; called by muse, mutect2, varscan2
- BIRC6 | c.10986C>G p.D3662E | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1410804458; called by muse, mutect2, varscan2
- C3 | c.1910G>C p.G637A | Missense Mutation (SNP) | VAF 98/402 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as COSV99836443; called by muse, mutect2, varscan2
- CACNA1F | c.2398G>T p.G800C | Missense Mutation (SNP) | VAF 53/408 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV100544913; called by muse, mutect2, varscan2
- CCNYL3 | n.878C>A | Splice Region (SNP) | VAF 42/212 reads (20%) | catalogued as rs1567578031; called by muse, mutect2, varscan2
- CDH10 | c.2278C>A p.Q760K | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV100052094, COSV99072653; called by muse, mutect2
- CDH12 | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 33/297 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV66404594; called by muse, mutect2, varscan2
- CEBPE | c.356C>A p.A119E | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs752134859, COSV52830766; called by muse, mutect2, varscan2
- CELSR2 | c.5753G>A p.S1918N | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as rs1557734144, COSV54780012; called by muse, varscan2
- CENPF | c.6757G>T p.E2253* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV65276891; called by muse, mutect2, varscan2
- CHRNA1 | c.52G>T p.V18F | Missense Mutation (SNP) | VAF 65/654 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.197); catalogued as COSV53682806, COSV53684609; called by muse, mutect2
- CNGB3 | c.248C>T p.T83I | Missense Mutation (SNP) | VAF 22/303 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs761822317, COSV60691040; called by muse, mutect2
- CNGB3 | c.155C>A p.S52Y | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1348237273, COSV60687435; called by muse, mutect2
- CNOT4 | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV59654161; called by muse, mutect2, varscan2
- COL7A1 | c.6007G>T p.G2003W | Missense Mutation (SNP) | VAF 74/287 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960408; called by muse, mutect2, varscan2
- CR2 | c.2591G>C p.G864A | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.21); catalogued as COSV100889569, COSV100889683; called by muse, mutect2, varscan2
- CRYBB2 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 49/442 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.112); catalogued as COSV101236772; called by muse, mutect2, varscan2
- CT47B1 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 88/824 reads (11%) | catalogued as COSV100988975; called by muse, varscan2
- CUX2 | c.2189G>T p.R730L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV55628451; called by muse, mutect2, varscan2
- CWH43 | c.926G>C p.G309A | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.456); catalogued as COSV56938999; called by muse, mutect2, varscan2
- DAB1 | c.973G>A p.G325S (on ENST00000371231; = p.G292S on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs200606976; called by muse, mutect2, varscan2
- DACH2 | c.792G>T p.W264C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV64190917; called by muse, mutect2, varscan2
- DCAF12L1 | c.425G>C p.R142T | Missense Mutation (SNP) | VAF 124/395 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs929945930, COSV100948186; called by muse, mutect2, varscan2
- DCC | c.3085G>T p.G1029* | Nonsense Mutation (SNP) | VAF 28/170 reads (16%) | catalogued as COSV59114740; called by muse, mutect2, varscan2
- DEFB108B | c.58+2T>A p.X20_splice | Splice Site (SNP) | VAF 15/64 reads (23%) | catalogued as rs753520410; called by muse, mutect2, varscan2
- DMD | c.5410G>T p.G1804W | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV63755584; called by muse, mutect2
- DRG1 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 26/203 reads (13%) | catalogued as COSV58918668; called by muse, mutect2, varscan2
- DSG1 | c.1688-1G>A p.X563_splice | Splice Site (SNP) | VAF 64/308 reads (21%) | catalogued as CS073472; called by muse, varscan2
- EFCAB6 | c.3174G>T p.E1058D | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV53073107; called by muse, varscan2
- EHMT1 | c.3632G>T p.R1211L | Missense Mutation (SNP) | VAF 48/344 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs751046687, COSV66044766; called by muse, mutect2, varscan2
- EPG5 | c.1479G>T p.W493C | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99957149; called by muse, mutect2, varscan2
- EPHA5 | c.2455T>A p.F819I | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56643391, COSV56648267; called by muse, mutect2, varscan2
- EPHA8 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 86/360 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1390798586, COSV51262442; called by muse, mutect2, varscan2
- EYA1 | c.305C>A p.S102Y | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as COSV100379816; called by muse, mutect2
- FAM47C | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.742); catalogued as rs371381467; called by muse, mutect2, varscan2
- FAM47C | c.2344C>T p.R782W | Missense Mutation (SNP) | VAF 37/311 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1387751693, COSV100792352; called by muse, mutect2, varscan2
- FARP2 | c.1677+1G>T p.X559_splice | Splice Site (SNP) | VAF 54/215 reads (25%) | catalogued as rs148642151, COSV50881241; called by muse, mutect2, varscan2
- FBXL20 | c.944G>A p.S315N | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs902064201, COSV99234241; called by muse, mutect2, varscan2
- FCRL2 | c.272G>T p.W91L | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs149860991; called by muse, mutect2, varscan2
- FCRL5 | c.2732T>C p.V911A | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.81); catalogued as rs749544661; called by muse, mutect2, varscan2
- FERD3L | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV51762526; called by muse, mutect2, varscan2
- FOXL1 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.2); catalogued as rs1477009659; called by muse, mutect2
- FOXO4 | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 38/259 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as COSV100446787; called by muse, mutect2, varscan2
- FREM2 | c.7726G>T p.G2576* | Nonsense Mutation (SNP) | VAF 26/85 reads (31%) | catalogued as COSV54852834; called by muse, mutect2, varscan2
- FREM3 | c.3017G>T p.R1006L | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV61679111; called by muse, mutect2, varscan2
- FSIP2 | c.18419C>A p.P6140Q | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100556916; called by muse, varscan2
- GABRB2 | c.1334G>T p.G445V (on ENST00000274547; = p.G407V on NM_000813.3) | Missense Mutation (SNP) | VAF 82/365 reads (22%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.61); catalogued as rs781071477, COSV50940637; called by muse, mutect2, varscan2
- GGN | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as rs769199866; called by muse, mutect2, varscan2
- GPR101 | c.909C>A p.S303R | Missense Mutation (SNP) | VAF 44/457 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.458); catalogued as COSV53239401, COSV53240959; called by muse, mutect2
- GTF3C1 | c.5461G>T p.D1821Y | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV62242765; called by muse, mutect2, varscan2
- GYPC | c.109C>A p.P37T | Missense Mutation (SNP) | VAF 101/483 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99391631; called by muse, mutect2, varscan2
- H1-7 | c.661G>T p.V221L | Missense Mutation (SNP) | VAF 81/626 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV58602336; called by muse, mutect2, varscan2
- HEPH | c.529G>T p.D177Y (on ENST00000343002; = p.D231Y on NM_138737.5) | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57967043; called by muse, mutect2, varscan2
- HPS5 | c.949C>T p.Q317* (on ENST00000349215 / NM_181507.2; = p.Q203* on NM_007216.4) | Nonsense Mutation (SNP) | VAF 25/170 reads (15%) | catalogued as COSV100752314; called by muse, mutect2, varscan2
- IGHM | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 118/576 reads (20%) | SIFT tolerated (0.19); catalogued as rs1466347721; called by muse, mutect2, varscan2
- IGLV2-18 | c.286A>G p.I96V | Missense Mutation (SNP) | VAF 63/448 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.101); catalogued as rs374060837; called by muse, mutect2, varscan2
- IGSF1 | c.1389C>G p.F463L | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV63836846; called by muse, mutect2, varscan2
- IL20RA | c.168G>A p.W56* | Nonsense Mutation (SNP) | VAF 41/120 reads (34%) | catalogued as rs908493206; called by muse, mutect2, varscan2
- ING5 | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs754232441; called by muse, mutect2, varscan2
- INHBA | c.295G>C p.G99R | Missense Mutation (SNP) | VAF 38/519 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54226737; called by muse, mutect2
- IRF6 | c.530G>T p.S177I | Missense Mutation (SNP) | VAF 86/412 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as CD092404; called by muse, mutect2, varscan2
- IRX2 | c.491G>T p.W164L | Missense Mutation (SNP) | VAF 90/1171 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57412891; called by muse, mutect2
- ITGAL | c.1730G>C p.G577A | Missense Mutation (SNP) | VAF 61/399 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs778948720, COSV63324297; called by muse, mutect2, varscan2
- ITGB3 | c.31T>C p.W11R | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs1022839092, CM153647; called by muse, mutect2, varscan2
- KPNA2 | c.385G>A p.G129S | Missense Mutation (SNP) | VAF 60/278 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs372495891; called by muse, mutect2, varscan2
- KRT5 | c.1645G>T p.G549W | Missense Mutation (SNP) | VAF 125/384 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV52861619; called by muse, mutect2
- LCE2C | c.162C>A p.S54R | Missense Mutation (SNP) | VAF 67/511 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs761711794, COSV64228230; called by muse, mutect2, varscan2
- LMBRD2 | c.751G>C p.V251L | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.069); catalogued as rs1256555316; called by muse, mutect2
- LRFN1 | c.1492G>T p.D498Y | Missense Mutation (SNP) | VAF 124/312 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50476813; called by muse, mutect2, varscan2
- LRFN1 | c.1056C>A p.D352E | Missense Mutation (SNP) | VAF 196/624 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV50437715, COSV50487480; called by muse, mutect2, varscan2
- LRRD1 | c.2249G>T p.R750L | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.048); catalogued as COSV58467806; called by muse, mutect2, varscan2
- LRRIQ3 | c.1196G>T p.R399L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs202037480, COSV63041614, COSV99063517; called by mutect2, varscan2
- MAGEA11 | c.234G>T p.R78S | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100290448, COSV60756977; called by muse, mutect2, varscan2
- MALRD1 | c.5911G>T p.D1971Y | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63196615; called by muse, mutect2
- MAPK10 | c.566G>T p.R189L (on ENST00000359221 / NM_001351625.2; = p.R227L on NM_002753.5) | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV60382973; called by muse, mutect2, varscan2
- MASP1 | c.62C>A p.T21N | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as rs1062049; called by muse, mutect2, varscan2
- MDFIC | c.186G>T p.W62C | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as COSV57567118; called by muse, varscan2
- MED12L | c.6331C>A p.Q2111K | Missense Mutation (SNP) | VAF 53/252 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV56388190; called by mutect2, varscan2
- MMP28 | c.668G>T p.R223L | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs372881071; called by muse, mutect2, varscan2
- MS4A2 | c.210G>C p.M70I | Missense Mutation (SNP) | VAF 73/215 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV54011848, COSV99627363; called by muse, mutect2, varscan2
- MTR | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 60/278 reads (22%) | catalogued as COSV63968157; called by muse, mutect2, varscan2
- MXRA5 | c.7814G>T p.G2605V | Missense Mutation (SNP) | VAF 64/428 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as COSV54238881; called by muse, mutect2, varscan2
- MYH6 | c.3284A>T p.K1095M | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1184174539; called by muse, mutect2, varscan2
- MYT1 | c.1124G>T p.R375L | Missense Mutation (SNP) | VAF 80/387 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV60515893; called by muse, mutect2, varscan2
- NAP1L3 | c.1375G>T p.D459Y | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59077921; called by muse, mutect2, varscan2
- NEB | c.10631C>A p.P3544Q | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51429766; called by muse, mutect2, varscan2
- NOSIP | c.834+1G>T p.X278_splice | Splice Site (SNP) | VAF 64/201 reads (32%) | catalogued as rs1444667339; called by muse, mutect2, varscan2
- NOX1 | c.1489A>G p.T497A | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779428704; called by muse, mutect2
- NPAS4 | c.967C>A p.R323S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV60652857; called by muse, mutect2, varscan2
- NR4A2 | c.1252C>T p.R418W | Missense Mutation (SNP) | VAF 54/400 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776353431, COSV59893221; called by muse, mutect2, varscan2
- NRIP1 | c.2558G>T p.C853F | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs771165207; called by muse, mutect2, varscan2
- NRK | c.1771del p.L591Cfs*22 | Frame Shift Del (DEL) | VAF 31/252 reads (12%) | catalogued as COSV54602043; called by mutect2, pindel, varscan2
- NRXN1 | c.3614C>A p.A1205E | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.858); catalogued as rs1377505157, COSV60509569; called by muse, mutect2
- NUP62 | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as rs1437558219; called by muse, mutect2, varscan2
- NYNRIN | c.5122C>T p.L1708F | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.881); catalogued as rs1446536675; called by muse, mutect2, varscan2
- OR13C8 | c.853G>T p.G285* | Nonsense Mutation (SNP) | VAF 15/89 reads (17%) | catalogued as COSV58612511; called by muse, mutect2, varscan2
- OR1L6 | c.568C>A p.H190N (on ENST00000373684; = p.H154N on NM_001004453.2) | Missense Mutation (SNP) | VAF 27/329 reads (8%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.815); catalogued as COSV100490993; called by muse, mutect2
- OR2B6 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV55128598; called by muse, mutect2, varscan2
- OR2F2 | c.894G>C p.K298N | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV68832783; called by muse, mutect2, varscan2
- OR2T2 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 87/709 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373307163; called by muse, mutect2, varscan2
- OR4K17 | c.397A>G p.M133V | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100210472; called by muse, mutect2, varscan2
- OR5D13 | c.258C>A p.N86K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs763757727, COSV62334485, COSV62334932; called by muse, mutect2, varscan2
- OTOL1 | c.835C>A p.R279S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV60006817; called by muse, mutect2
- PCDH11X | c.1969G>T p.A657S | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV100016656; called by muse, mutect2, varscan2
- PCDHA3 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 232/817 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.16); catalogued as rs1554122295, COSV63542222; called by muse, mutect2, varscan2
- PCDHB7 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50773162; called by muse, mutect2
- PCDHB9 | c.1169C>A p.P390H | Missense Mutation (SNP) | VAF 87/329 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1563944225, COSV53383107; called by muse, mutect2, varscan2
- PCLO | c.12973G>T p.D4325Y | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61653847; called by muse, mutect2, varscan2
- PHKB | c.1906G>T p.D636Y | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768125861; called by muse, mutect2
- PKHD1 | c.6886A>G p.I2296V | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.061); catalogued as rs1232982233; called by muse, mutect2, varscan2
- PLBD2 | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.253); catalogued as rs1178004154; called by muse, mutect2, varscan2
- PPFIA2 | c.2202G>T p.R734S | Missense Mutation (SNP) | VAF 64/333 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as COSV100334026, COSV61041115; called by muse, mutect2, varscan2
- PPP6R2 | c.1360C>T p.Q454* | Nonsense Mutation (SNP) | VAF 29/187 reads (16%) | catalogued as rs1415265385; called by muse, mutect2, varscan2
- PRDM9 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 85/599 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as COSV99691652; called by muse, mutect2, varscan2
- PRDM9 | c.1747A>T p.R583W | Missense Mutation (SNP) | VAF 64/814 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs755014262; called by muse, mutect2
- PRG4 | c.4090G>A p.G1364S | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs200043407, COSV63354838; called by muse, mutect2, varscan2
- PRKCB | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.039); catalogued as COSV57782854; called by muse, mutect2, varscan2
- PRMT5 | c.634C>G p.L212V | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV99362736; called by muse, mutect2, varscan2
- PRSS58 | c.123C>A p.C41* | Nonsense Mutation (SNP) | VAF 24/187 reads (13%) | catalogued as rs562510369, COSV73488499; called by muse, mutect2, varscan2
- PTPRT | c.2195C>G p.S732C | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV61968230, COSV61976818; called by muse, mutect2, varscan2
- PXDNL | c.490G>T p.G164W | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1398695324, COSV99080548; called by muse, mutect2, varscan2
- RAB6C | c.429G>T p.R143S | Missense Mutation (SNP) | VAF 78/342 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.035); catalogued as COSV101308520, COSV69339914; called by muse, mutect2, varscan2
- RELN | c.3023G>T p.R1008L | Missense Mutation (SNP) | VAF 56/708 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58985444; called by muse, mutect2
- RERE | c.3437G>A p.R1146Q | Missense Mutation (SNP) | VAF 42/329 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100556590; called by muse, mutect2, varscan2
- RFPL4B | c.569A>T p.H190L | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as rs1157043703; called by muse, mutect2, varscan2
- RPL6 | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as rs1278348428; called by muse, mutect2, varscan2
- RTL3 | c.151C>A p.L51I | Missense Mutation (SNP) | VAF 97/292 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as rs762824732; called by muse, mutect2, varscan2
- RXFP1 | c.1204C>G p.L402V | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57053370; called by muse, mutect2, varscan2
- RXRG | c.1201C>T p.L401F | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100717249; called by muse, mutect2, varscan2
- RYR1 | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 77/445 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62094394; called by muse, mutect2, varscan2
- SCN1A | c.5851G>C p.A1951P (on ENST00000303395 / NM_001202435.3; = p.A1940P on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.081); catalogued as rs376656165; called by muse, mutect2, varscan2
- SCN9A | c.4942G>A p.G1648S (on ENST00000303354; = p.G1637S on NM_002977.3) | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1231385530; called by muse, mutect2
- SELE | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 16/389 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as rs934207923; called by muse, mutect2
- SEMA3E | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as rs1562764382; called by muse, mutect2, varscan2
- SFMBT2 | c.2144C>G p.S715W | Missense Mutation (SNP) | VAF 46/444 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62808087; called by muse, mutect2, varscan2
- SI | c.1915G>A p.A639T | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.053); catalogued as rs1398853459; called by muse, mutect2, varscan2
- SLAMF1 | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as rs1558007065; called by muse, mutect2, varscan2
- SLC30A10 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 33/309 reads (11%) | catalogued as COSV63072907; called by muse, mutect2, varscan2
- SORCS1 | c.3165G>A p.Q1055= | Splice Region (SNP) | VAF 16/132 reads (12%) | catalogued as COSV53886316; called by muse, mutect2, varscan2
- SPTA1 | c.6310G>T p.E2104* | Nonsense Mutation (SNP) | VAF 50/153 reads (33%) | catalogued as COSV100935697; called by muse, mutect2, varscan2
- SPTA1 | c.1066C>A p.R356S | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as COSV63748977; called by muse, mutect2, varscan2
- SRRM3 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 87/232 reads (38%) | catalogued as rs1554609863; called by muse, mutect2, varscan2
- STOML3 | c.481T>A p.L161I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1046470265; called by muse, mutect2, varscan2
- TAF3 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 18/133 reads (14%) | catalogued as COSV60208352; called by muse, mutect2, varscan2
- TBC1D10B | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV69504986; called by muse, mutect2
- TBC1D9 | c.1375G>T p.A459S | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV71307347; called by muse, mutect2, varscan2
- TBCE | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 68/276 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM162188; called by muse, mutect2, varscan2
- TEKT2 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 112/978 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs754180810, COSV52880436; called by muse, mutect2, varscan2
- TENM1 | c.3806C>A p.T1269K | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.319); catalogued as rs200542551, COSV64440173; called by muse, mutect2, varscan2
- TEX13B | c.680C>A p.A227D | Missense Mutation (SNP) | VAF 191/552 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV57203785; called by muse, mutect2, varscan2
- TFPI | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.095); catalogued as COSV51904494; called by muse, mutect2, varscan2
- TGIF2LX | c.551C>A p.T184N | Missense Mutation (SNP) | VAF 76/967 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.276); catalogued as COSV52215010; called by muse, mutect2
- TIGD5 | c.1678G>T p.A560S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1191768293; called by muse, mutect2, varscan2
- TMEM225 | c.108G>C p.L36F | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66693984; called by muse, mutect2, varscan2
- TNFAIP1 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 108/495 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs782150913, COSV50228609; called by muse, mutect2, varscan2
- TPO | c.1234C>A p.R412S | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100222679; called by muse, mutect2, varscan2
- TREX2 | c.782G>T p.G261V (on ENST00000334497; = p.G218V on NM_080701.3) | Missense Mutation (SNP) | VAF 66/757 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57849624; called by muse, mutect2
- TRIM33 | c.2527G>T p.A843S | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1403075722; called by muse, mutect2, varscan2
- TRIM49C | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 76/239 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.378); catalogued as rs775011866; called by muse, mutect2, varscan2
- TRPM3 | c.890C>A p.A297D (on ENST00000357533 / NM_001366142.2; = p.A142D on NM_020952.6) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV62468052; called by muse, mutect2, varscan2
- TSHZ2 | c.2253C>A p.S751R | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.315); catalogued as COSV61591336; called by muse, mutect2
- TTC21A | c.2157-1G>T p.X719_splice | Splice Site (SNP) | VAF 67/243 reads (28%) | catalogued as rs1441823954; called by muse, mutect2, varscan2
- TTN | c.2350G>T p.G784* (on ENST00000591111; = p.G738* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 26/264 reads (10%) | catalogued as COSV60230919; called by muse, mutect2
- TUBB8B | c.944C>A p.A315D | Missense Mutation (SNP) | VAF 143/619 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as COSV58267553; called by muse, varscan2
- TUFM | c.262G>C p.G88R | Missense Mutation (SNP) | VAF 67/446 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs11542263; called by muse, mutect2, varscan2
- UGT3A1 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57097122; called by muse, mutect2, varscan2
- USH2A | c.12094G>C p.G4032R | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM1514190; called by muse, mutect2, varscan2
- USH2A | c.7399C>A p.P2467T | Missense Mutation (SNP) | VAF 62/299 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as COSV56453706; called by muse, mutect2, varscan2
- VAV3 | c.1350C>A p.Y450* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as rs936552092, COSV58382362; called by muse, mutect2, varscan2
- VGLL3 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs773654733; called by muse, mutect2, varscan2
- VPS39 | c.2393A>G p.N798S (on ENST00000348544 / NM_001301138.2; = p.N787S on NM_015289.5) | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs759992070; called by muse, mutect2, varscan2
- VWDE | c.686G>T p.R229M | Missense Mutation (SNP) | VAF 44/321 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs907845942; called by muse, mutect2, varscan2
- WFIKKN2 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 64/419 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201598038; called by muse, mutect2, varscan2
- XPNPEP2 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs147873278, COSV64367848; called by muse, mutect2, varscan2
- ZAR1 | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs770550111; called by muse, mutect2, varscan2
- ZNF385D | c.1114C>A p.P372T | Missense Mutation (SNP) | VAF 159/617 reads (26%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.663); catalogued as COSV99873155; called by muse, mutect2, varscan2
- ZNF395 | c.1439G>T p.R480L | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60429682; called by muse, mutect2, varscan2
- ZNF449 | c.830C>A p.P277Q | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV59348278; called by muse, mutect2, varscan2
- ZNF471 | c.405G>T p.M135I | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs774362688; called by muse, mutect2, varscan2
- ZNF679 | c.39G>A p.M13I | Missense Mutation (SNP) | VAF 166/523 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV55382339; called by muse, mutect2, varscan2
- ZP4 | c.1297G>T p.A433S | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.734); catalogued as rs1217352211; called by muse, varscan2
- ZP4 | c.737G>C p.R246T | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as COSV100850625, COSV100850742; called by muse, mutect2
- ZP4 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 27/271 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs763337523; called by muse, mutect2
- ZPR1 | c.956C>G p.S319* | Nonsense Mutation (SNP) | VAF 12/205 reads (6%) | catalogued as COSV57063892; called by muse, mutect2
- ZSCAN9 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs762408614, COSV52851195; called by muse, mutect2, varscan2
- ABCA12 | c.799T>A p.S267T | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ABCA13 | c.14173A>T p.K4725* | Nonsense Mutation (SNP) | VAF 38/159 reads (24%) | called by muse, varscan2
- ABCA4 | c.1947C>G p.I649M | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ABCB7 | c.2068C>A p.H690N (on ENST00000373394 / NM_001271696.3; = p.H691N on NM_004299.6) | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCC11 | c.2080C>G p.Q694E | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2
- ABCD4 | c.203A>T p.Y68F | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- ABHD4 | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- ABHD6 | c.682-1G>T p.X228_splice | Splice Site (SNP) | VAF 49/173 reads (28%) | called by muse, mutect2, varscan2
- AC092718.8 | c.381dup p.A128Cfs*13 | Frame Shift Ins (INS) | VAF 26/244 reads (11%) | called by mutect2, pindel, varscan2
- AC244197.3 | c.801C>G p.D267E | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ACOD1 | c.1442C>A p.S481Y | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ACTN1 | c.762G>T p.K254N | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- ADAM30 | c.1205G>T p.C402F | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTS12 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 69/248 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADAMTS16 | c.1208-2A>C p.X403_splice | Splice Site (SNP) | VAF 40/284 reads (14%) | called by muse, varscan2
- ADAMTS4 | c.1539G>T p.Q513H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS4 | c.1538A>C p.Q513P | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS7 | c.925C>A p.H309N | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY2 | c.1773G>A p.E591= | Splice Region (SNP) | VAF 16/137 reads (12%) | called by muse, mutect2, varscan2
- ADCY2 | c.2345C>T p.A782V | Missense Mutation (SNP) | VAF 62/377 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADGRA1 | c.574G>T p.V192L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ADGRE1 | c.143C>G p.T48S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- ADGRV1 | c.9163G>T p.E3055* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- ADH1A | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- AFF2 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 54/549 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AGTR1 | c.979C>A p.H327N | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AHNAK | c.8166G>T p.K2722N | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- AHNAK2 | c.13060G>T p.D4354Y | Missense Mutation (SNP) | VAF 65/474 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHRR | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 53/638 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AKAP9 | c.3339G>T p.M1113I | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, varscan2
- AMER3 | c.1651G>T p.A551S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ANGPTL4 | c.120G>C p.E40D | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0.055); called by muse, mutect2
- ANK1 | c.4195G>T p.G1399W | Missense Mutation (SNP) | VAF 55/800 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); called by muse, mutect2
- ANTKMT | c.327G>T p.W109C | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- AP1B1 | c.441G>T p.K147N | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AP1B1 | c.439A>T p.K147* | Nonsense Mutation (SNP) | VAF 42/244 reads (17%) | called by muse, mutect2
- APOB | c.7563C>A p.D2521E | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARID1B | c.2072G>A p.G691E | Missense Mutation (SNP) | VAF 134/500 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARMCX2 | c.1414G>T p.V472L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ARSG | c.1109C>A p.P370Q | Missense Mutation (SNP) | VAF 39/345 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASAH2 | c.1856C>A p.T619K | Missense Mutation (SNP) | VAF 165/500 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0.133); called by muse, varscan2
- ASB12 | c.175C>A p.R59S | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ASB17 | c.67C>A p.L23I | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASTN2 | c.1804G>T p.V602L (on ENST00000313400 / NM_001365069.1; = p.V551L on NM_014010.5) | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ASXL2 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.061); called by muse, varscan2
- ATG4A | c.297G>T p.W99C | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ATP10D | c.4280A>C p.*1427Sext*45 | Nonstop Mutation (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- ATP2B2 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 107/314 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP5F1A | c.807G>A p.M269I | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATP6AP1 | c.972G>A p.K324= | Splice Region (SNP) | VAF 24/232 reads (10%) | called by muse, mutect2, varscan2
- BASP1 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 73/709 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BUD13 | c.204G>C p.K68N | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- C20orf85 | c.386T>A p.L129Q | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACNA1D | c.3004A>G p.K1002E (on ENST00000350061 / NM_001128840.3; = p.K1022E on NM_000720.4) | Missense Mutation (SNP) | VAF 83/259 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1D | c.4654G>T p.A1552S (on ENST00000350061 / NM_001128840.3; = p.A1572S on NM_000720.4) | Missense Mutation (SNP) | VAF 75/231 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CACNA2D4 | c.199T>A p.W67R | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- CAMK2D | c.1126G>T p.G376C | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CAMP | c.224A>G p.D75G (on ENST00000296435; = p.D72G on NM_004345.5) | Missense Mutation (SNP) | VAF 113/314 reads (36%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CAPN12 | c.1243C>A p.P415T | Missense Mutation (SNP) | VAF 62/264 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CARD10 | c.2371A>G p.N791D | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.76); called by muse, mutect2
- CASQ2 | c.782G>C p.W261S | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- CCAR1 | c.810G>C p.Q270H | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, varscan2
- CCDC178 | c.1145C>G p.S382* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | called by muse, varscan2
- CCNY | c.324T>A p.D108E | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- CCT6A | c.925G>T p.G309C | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCT8L2 | c.571A>C p.I191L | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.141); called by muse, mutect2
- CD1E | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 51/289 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CD22 | c.173T>C p.L58P | Missense Mutation (SNP) | VAF 83/479 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CD22 | c.310C>A p.L104M | Missense Mutation (SNP) | VAF 54/425 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- CDH1 | c.2633G>T p.G878V | Missense Mutation (SNP) | VAF 82/601 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH12 | c.2179G>T p.D727Y | Missense Mutation (SNP) | VAF 72/552 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CDH12 | c.1774T>G p.C592G | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CDH7 | c.134C>A p.T45N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.058); called by muse, varscan2
- CELA2A | c.165C>A p.Y55* | Nonsense Mutation (SNP) | VAF 99/411 reads (24%) | called by muse, mutect2, varscan2
- CFAP46 | c.2484C>G p.I828M | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- CFHR5 | c.1097G>T p.R366M | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHD5 | c.134T>A p.V45E | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- CHD9 | c.3073A>C p.T1025P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CHRM3 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 69/355 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLEC2A | c.504C>A p.S168R | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- CLEC2B | c.275G>A p.W92* | Nonsense Mutation (SNP) | VAF 40/136 reads (29%) | called by muse, mutect2, varscan2
- CLIP2 | c.1440G>T p.E480D | Missense Mutation (SNP) | VAF 115/356 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- CLVS1 | c.248G>A p.R83K | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- CLYBL | c.412G>C p.V138L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CMYA5 | c.4889A>C p.Q1630P | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, varscan2
- CNGB1 | c.2078T>A p.L693Q | Missense Mutation (SNP) | VAF 95/753 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CNTN1 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- CNTNAP2 | c.921C>A p.Y307* | Nonsense Mutation (SNP) | VAF 74/262 reads (28%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.2234A>C p.E745A | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- COBL | c.3476G>T p.G1159V | Missense Mutation (SNP) | VAF 74/294 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COBL | c.3475G>T p.G1159W | Missense Mutation (SNP) | VAF 76/302 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL11A1 | c.893C>A p.T298K | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.972); called by muse, mutect2
- COL12A1 | c.7249T>A p.W2417R | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- COL22A1 | c.3663T>A p.P1221= | Splice Region (SNP) | VAF 25/123 reads (20%) | called by muse, mutect2, varscan2
- CPE | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPZ | c.57del p.P20Rfs*63 (on ENST00000360986 / NM_001014447.3; = p.P20Rfs*52 on NM_003652.3) | Frame Shift Del (DEL) | VAF 16/168 reads (10%) | called by mutect2, pindel, varscan2
- CR1 | c.159G>T p.R53S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- CRB2 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CROCC2 | c.2005G>T p.G669W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2
- CRY1 | c.689G>T p.W230L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- CSMD3 | c.8631C>A p.H2877Q (on ENST00000297405 / NM_001363185.1; = p.H2708Q on NM_052900.3) | Missense Mutation (SNP) | VAF 45/234 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSMD3 | c.5396-1G>T p.X1799_splice (on ENST00000297405 / NM_001363185.1; = p.X1695_splice on NM_052900.3) | Splice Site (SNP) | VAF 16/214 reads (7%) | called by muse, mutect2
- CSMD3 | c.4465C>A p.L1489I (on ENST00000297405 / NM_001363185.1; = p.L1385I on NM_052900.3) | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CSNK1D | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 58/923 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.432); called by muse, mutect2
- CT47B1 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 196/721 reads (27%) | called by muse, mutect2, varscan2
- CTNND2 | c.1075C>A p.L359M | Missense Mutation (SNP) | VAF 33/529 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- CUBN | c.4313T>A p.V1438E | Missense Mutation (SNP) | VAF 83/366 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CYP4F11 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CYP8B1 | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DCAF4L2 | c.688C>A p.Q230K | Missense Mutation (SNP) | VAF 110/567 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.267); called by muse, varscan2
- DCAF6 | c.1780G>T p.G594W (on ENST00000312263 / NM_001349778.1; = p.G614W on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.412); called by muse, varscan2
- DCSTAMP | c.191C>A p.S64Y | Missense Mutation (SNP) | VAF 126/667 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- DDX52 | c.1276A>G p.K426E | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, varscan2
- DDX60 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- DENND3 | c.1592_1594delinsTT p.Q531Lfs*11 | Frame Shift Del (DEL) | VAF 87/361 reads (24%) | called by pindel, varscan2*
- DHCR24 | c.883A>T p.S295C | Missense Mutation (SNP) | VAF 62/480 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DLL3 | c.1205A>T p.N402I | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DMRTA2 | c.554dup p.S186Lfs*9 | Frame Shift Ins (INS) | VAF 17/76 reads (22%) | called by mutect2, pindel, varscan2
- DNER | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 29/286 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- DOCK11 | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DRAXIN | c.338T>A p.L113Q | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- E2F7 | c.1784G>T p.R595L | Missense Mutation (SNP) | VAF 48/490 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- EFR3A | c.2023A>T p.S675C | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EHMT1 | c.1360G>T p.G454C | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- EIF2AK3 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); called by muse, varscan2
- ELOVL4 | c.226C>G p.R76G | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.414); called by muse, mutect2
- ENAH | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENGASE | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 51/242 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ENOX2 | c.373C>A p.P125T (on ENST00000338144 / NM_001382520.1; = p.P96T on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2
- EPB41L3 | c.1904G>T p.C635F | Missense Mutation (SNP) | VAF 44/348 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- EPHA7 | c.2110G>A p.G704R | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPS8 | c.587C>G p.P196R | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- ERI2 | c.1592G>A p.G531D | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by mutect2, varscan2
- ESPNL | c.2347G>T p.G783W | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- EXD2 | c.1287dup p.I430Hfs*9 (on ENST00000312994 / NM_001193362.1; = p.I305Hfs*9 on NM_018199.3) | Frame Shift Ins (INS) | VAF 31/147 reads (21%) | called by mutect2, pindel, varscan2
- F2R | c.742G>T p.G248W | Missense Mutation (SNP) | VAF 15/325 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.147); called by muse, mutect2
- F8 | c.964C>A p.L322I | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.674); called by muse, mutect2
- F8 | c.770T>A p.V257E | Missense Mutation (SNP) | VAF 32/355 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2
- FAM135B | c.2011G>T p.V671L | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM155B | c.795C>A p.D265E | Missense Mutation (SNP) | VAF 46/494 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.292); called by muse, mutect2
- FAM177B | c.174T>C p.P58= | Splice Region (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2
- FAM47C | c.598C>A p.P200T | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- FAM90A1 | c.1177A>T p.R393* | Nonsense Mutation (SNP) | VAF 122/1904 reads (6%) | called by muse, mutect2
- FCGBP | c.1984C>A p.P662T | Missense Mutation (SNP) | VAF 48/271 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- FCRL4 | c.1401G>T p.Q467H | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- FGFR4 | c.1250A>G p.Q417R | Missense Mutation (SNP) | VAF 11/215 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- FIGN | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 11/154 reads (7%) | PolyPhen probably damaging (0.98); called by muse, mutect2
- FIGNL1 | c.154del p.Q52Rfs*28 | Frame Shift Del (DEL) | VAF 15/123 reads (12%) | called by mutect2, pindel, varscan2
- FLG | c.8242T>C p.S2748P | Missense Mutation (SNP) | VAF 136/505 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FLG | c.1295C>A p.S432* | Nonsense Mutation (SNP) | VAF 253/640 reads (40%) | called by muse, mutect2, varscan2
- FOXD4L5 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 37/399 reads (9%) | called by mutect2, varscan2
- FOXP2 | c.1234C>G p.R412G | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); called by muse, mutect2
- FOXR2 | c.492C>A p.D164E | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FSHB | c.360C>G p.S120R | Missense Mutation (SNP) | VAF 37/354 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- FSIP2 | c.15323C>T p.P5108L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- FUS | c.1220G>C p.R407P | Missense Mutation (SNP) | VAF 57/430 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- FUT5 | c.622T>C p.W208R | Missense Mutation (SNP) | VAF 65/595 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAB4 | c.1348C>A p.P450T | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GABRG2 | c.926G>A p.S309N (on ENST00000361925 / NM_001375343.1; = p.S269N on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GABRG3 | c.547C>A p.H183N | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GADL1 | c.36C>A p.D12E | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GAL3ST2 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- GALNT17 | c.1339C>T p.Q447* | Nonsense Mutation (SNP) | VAF 36/253 reads (14%) | called by muse, varscan2
- GALNT17 | c.1404+2T>A p.X468_splice | Splice Site (SNP) | VAF 70/245 reads (29%) | called by muse, varscan2
- GC | c.1352A>T p.N451I | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- GCM2 | c.1217G>C p.R406P | Missense Mutation (SNP) | VAF 142/422 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- GDA | c.311C>G p.T104S | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- GDF3 | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 50/167 reads (30%) | called by muse, mutect2, varscan2
- GFRAL | c.732C>A p.C244* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- GHRHR | c.256A>T p.S86C | Missense Mutation (SNP) | VAF 179/656 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- GLB1L3 | c.176T>A p.L59Q | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- GNGT2 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GPR33 | c.443T>A p.I148N | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- GPR42 | c.1010C>G p.T337S | Missense Mutation (SNP) | VAF 114/360 reads (32%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GRAMD2B | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.054); called by muse, mutect2
- GRIA1 | c.2271-1dup p.X757_splice | Splice Site (INS) | VAF 32/258 reads (12%) | called by mutect2, pindel, varscan2
- GSPT2 | c.1831G>T p.E611* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- GSTA2 | c.86A>T p.E29V | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GSTO2 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- GUCY2F | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.304); called by muse, mutect2
- GUCY2F | c.399G>T p.E133D | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.02); called by muse, mutect2
- GULP1 | c.675A>G p.I225M | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- H1-4 | c.332C>A p.A111E | Missense Mutation (SNP) | VAF 167/475 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HADHB | c.413G>T p.C138F | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- HEATR1 | c.563T>C p.F188S | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HECW1 | c.2732C>G p.A911G | Missense Mutation (SNP) | VAF 91/328 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- HERC1 | c.12506G>T p.G4169V | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- HERC1 | c.820del p.A274Lfs*20 | Frame Shift Del (DEL) | VAF 13/109 reads (12%) | called by mutect2, pindel, varscan2
- HLA-DQA2 | c.28G>T p.G10W | Missense Mutation (SNP) | VAF 155/413 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- HMCN1 | c.12172T>A p.C4058S | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- HMCN2 | c.14463G>T p.W4821C | Missense Mutation (SNP) | VAF 128/501 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- HMOX1 | c.104G>T p.R35M | Missense Mutation (SNP) | VAF 68/497 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- HOXB1 | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- HS3ST2 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.015); called by muse, mutect2
- HS3ST3A1 | c.696G>T p.M232I | Missense Mutation (SNP) | VAF 90/518 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- HYDIN | c.6560C>T p.P2187L | Missense Mutation (SNP) | VAF 46/350 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); called by mutect2, varscan2
- HYDIN | c.6558del p.I2188Sfs*17 | Frame Shift Del (DEL) | VAF 41/355 reads (12%) | called by mutect2, pindel, varscan2
- IGFL1 | c.203C>A p.T68K | Missense Mutation (SNP) | VAF 153/495 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGKV2D-28 | c.168C>A p.N56K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.146); called by mutect2, varscan2
- IGKV3-15 | c.100T>A p.S34T | Missense Mutation (SNP) | VAF 36/606 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.942); called by muse, mutect2
- IGSF11 | c.1007G>A p.S336N (on ENST00000393775 / NM_001015887.3; = p.S335N on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/396 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- INTS7 | c.1316A>T p.H439L | Missense Mutation (SNP) | VAF 142/681 reads (21%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IPO5 | c.91-2A>G p.X31_splice | Splice Site (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- IQSEC2 | c.3424A>T p.S1142C (on ENST00000642864 / NM_001111125.3; = p.S937C on NM_015075.2) | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IQSEC3 | c.156C>G p.S52R | Missense Mutation (SNP) | VAF 61/774 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.316); called by muse, mutect2
- IRAK1 | c.2069G>T p.S690I | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- ISLR | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 93/309 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ITGA4 | c.925T>A p.S309T | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- ITPR1 | c.2539G>A p.D847N (on ENST00000354582; = p.D832N on NM_002222.7) | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- JAML | c.625G>T p.V209L (on ENST00000356289 / NM_001098526.2; = p.V199L on NM_153206.3) | Missense Mutation (SNP) | VAF 182/451 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KCNC1 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- KCNH8 | c.1344G>C p.K448N | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNJ3 | c.1297T>A p.L433M | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- KCNJ3 | c.1488C>A p.N496K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, varscan2
- KDM5B | c.566A>G p.D189G | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- KDM5C | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 61/369 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIAA0100 | c.2203G>T p.V735L | Missense Mutation (SNP) | VAF 17/193 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KIAA0319 | c.597dup p.G200Wfs*15 | Frame Shift Ins (INS) | VAF 46/128 reads (36%) | called by mutect2, pindel, varscan2
- KIAA1549 | c.1576G>T p.G526C | Missense Mutation (SNP) | VAF 54/245 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- KIF1A | c.1871G>T p.R624L | Missense Mutation (SNP) | VAF 65/298 reads (22%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- KIF25 | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 62/187 reads (33%) | called by muse, mutect2, varscan2
- KIF2B | c.1682C>A p.A561E | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF6 | c.916C>G p.L306V | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIR3DL1 | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 139/450 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- KLHDC1 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 27/136 reads (20%) | called by muse, mutect2, varscan2
- KNTC1 | c.4141G>A p.V1381M | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- KRT28 | c.227del p.G76Efs*13 | Frame Shift Del (DEL) | VAF 46/319 reads (14%) | called by mutect2, pindel, varscan2
- KRT5 | c.1271C>A p.A424D | Missense Mutation (SNP) | VAF 197/647 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRTAP10-2 | c.632A>G p.Q211R | Missense Mutation (SNP) | VAF 69/615 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LCT | c.2554G>T p.A852S | Missense Mutation (SNP) | VAF 106/470 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LDB2 | c.505G>C p.V169L | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- LGR6 | c.1367T>G p.L456R (on ENST00000367278 / NM_001017403.1; = p.L404R on NM_021636.3) | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LHX3 | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LMBRD2 | c.750G>A p.E250= | Splice Region (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- LRFN5 | c.73G>T p.V25F | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- LRP1B | c.733G>T p.D245Y | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.172); called by mutect2, varscan2
- LRP2 | c.10609G>T p.D3537Y | Missense Mutation (SNP) | VAF 95/347 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP2 | c.5323G>A p.A1775T | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LRP2BP | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRC7 | c.3563del p.G1188Efs*11 (on ENST00000651989 / NM_001370785.2; = p.G1155Efs*11 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 38/328 reads (12%) | called by mutect2, pindel, varscan2
- LRRN2 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MAGEB6B | c.262G>T p.G88C | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- MAP3K21 | c.2432G>T p.C811F | Missense Mutation (SNP) | VAF 45/396 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- MAPK8IP3 | c.1537-1G>T p.X513_splice | Splice Site (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2, varscan2
- MARCO | c.783G>T p.R261S | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MARK1 | c.44C>A p.T15K | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, varscan2
- MED22 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 33/247 reads (13%) | called by muse, mutect2, varscan2
- MEMO1 | c.218_221del p.R73Ifs*88 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel, varscan2
- MGAM2 | c.3037C>T p.P1013S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MIS18BP1 | c.1113A>T p.Q371H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, varscan2
- MOGAT1 | c.315A>G p.I105M | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- MPP1 | c.520G>T p.D174Y | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MRPL45 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 62/356 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, varscan2
- MSN | c.738G>C p.R246S | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- MUC12 | c.728C>A p.S243Y (on ENST00000379442; = p.S100Y on NM_001164462.1) | Missense Mutation (SNP) | VAF 58/431 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- MUC12 | c.8693C>T p.T2898I (on ENST00000379442; = p.T2755I on NM_001164462.1) | Missense Mutation (SNP) | VAF 88/3598 reads (2%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); called by muse, mutect2
- MUC16 | c.3369T>A p.D1123E | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MUSK | c.2318C>A p.S773Y | Missense Mutation (SNP) | VAF 99/473 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MX1 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 106/671 reads (16%) | called by muse, mutect2, varscan2
- MYBPC3 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 79/264 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- MYH2 | c.4184C>A p.A1395D | Missense Mutation (SNP) | VAF 57/507 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH7 | c.3029T>A p.L1010H | Missense Mutation (SNP) | VAF 63/327 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NBAS | c.4723G>T p.A1575S | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NBPF26 | c.2446G>T p.E816* (on ENST00000620612; = p.E554* on NM_001351372.1) | Nonsense Mutation (SNP) | VAF 12/137 reads (9%) | called by muse, mutect2, varscan2
- NDUFA1 | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 40/522 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.858); called by muse, mutect2
- NECTIN3 | c.1102A>T p.T368S | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- NEK3 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- NFASC | c.2169T>A p.S723R (on ENST00000339876 / NM_001378329.1; = p.S719R on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/263 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- NLGN3 | c.2051A>T p.Q684L (on ENST00000358741 / NM_181303.2; = p.Q664L on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- NLRP1 | c.554G>C p.S185T | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NLRP3 | c.202A>T p.M68L | Missense Mutation (SNP) | VAF 72/657 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- NODAL | c.132G>T p.M44I | Missense Mutation (SNP) | VAF 87/252 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NOL4L | c.479T>A p.I160N | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NOVA1 | c.857C>G p.A286G | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.199); called by muse, mutect2
- NOVA1 | c.673G>T p.G225* | Nonsense Mutation (SNP) | VAF 27/193 reads (14%) | called by muse, mutect2, varscan2
- NPY2R | c.1025G>T p.C342F | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- NR2F1 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 74/278 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.209); called by muse, varscan2
- NSD2 | c.1691A>T p.D564V | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NTNG2 | c.373del p.L125Ffs*9 | Frame Shift Del (DEL) | VAF 89/370 reads (24%) | called by mutect2, pindel, varscan2
- NUP153 | c.157G>T p.G53W | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- OAS2 | c.1858G>T p.V620L | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ODF4 | c.538G>T p.G180C | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- OPA3 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 56/292 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OR11H12 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.045); called by mutect2, varscan2
- OR13C4 | c.831G>T p.E277D | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); called by mutect2, varscan2
- OR1E2 | c.328C>A p.L110I | Missense Mutation (SNP) | VAF 78/254 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- OR2D3 | c.821C>T p.T274I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.1); called by muse, varscan2
- OR2F2 | c.170C>A p.T57N | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- OR2M2 | c.819G>T p.M273I | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- OR2T3 | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 45/337 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2V2 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4A15 | c.494del p.P165Lfs*19 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | called by mutect2, varscan2
- OR52E4 | c.174C>A p.H58Q | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5K1 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- OR8H1 | c.248C>G p.A83G | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OSBPL11 | c.1905G>T p.W635C | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTOP1 | c.1591C>A p.P531T | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PAPPA | c.704G>T p.C235F | Missense Mutation (SNP) | VAF 48/234 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAPPA2 | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 52/477 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, varscan2
- PAPPA2 | c.4417A>T p.N1473Y | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGC5 | c.1897G>T p.A633S | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.156); called by muse, mutect2
- PDGFRA | c.2753C>A p.P918H | Missense Mutation (SNP) | VAF 121/644 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDZRN4 | c.1024C>A p.H342N (on ENST00000402685 / NM_001164595.2; = p.H84N on NM_013377.4) | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.645); called by muse, mutect2
- PHKA1 | c.3266G>A p.G1089E | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.742); called by muse, mutect2
- PKHD1L1 | c.9769C>A p.L3257M | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PLXNB3 | c.4634C>A p.T1545K | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- POLQ | c.3244T>G p.F1082V | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POU3F4 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 44/530 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.321); called by muse, mutect2
- PPAT | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PPM1L | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- PPP4R3C | c.1614G>T p.L538F | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRAMEF20 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 115/604 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- PRKD1 | c.2566G>T p.G856W | Missense Mutation (SNP) | VAF 32/293 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PROKR2 | c.181G>C p.A61P | Missense Mutation (SNP) | VAF 170/644 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- PRR14L | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- PRR33 | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PTPRN2 | c.702C>A p.D234E | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PUS1 | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.652); called by mutect2, varscan2
- RAB39B | c.455C>A p.T152K | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2
- RANBP2 | c.3954G>T p.Q1318H | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RELN | c.6290T>A p.L2097Q | Missense Mutation (SNP) | VAF 243/799 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- REXO1 | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- RFK | c.157G>T p.V53F | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- RIMS2 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 83/468 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- RIMS2 | c.3835A>G p.K1279E | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.057); called by muse, mutect2
- RP1L1 | c.5273C>A p.P1758H | Missense Mutation (SNP) | VAF 76/452 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- RPE65 | c.858+2T>A p.X286_splice | Splice Site (SNP) | VAF 42/177 reads (24%) | called by muse, mutect2, varscan2
- RPS2 | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 84/250 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- RRP8 | c.1136A>T p.N379I | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RTL9 | c.1498C>A p.P500T | Missense Mutation (SNP) | VAF 19/249 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.173); called by muse, mutect2
- RTL9 | c.2144C>G p.S715C | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- RUNX1T1 | c.1303A>T p.R435W (on ENST00000265814 / NM_001198628.1; = p.R408W on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RUSF1 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 20/174 reads (11%) | called by muse, mutect2, varscan2
- SALL1 | c.3901G>A p.A1301T | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SALL1 | c.2134C>A p.H712N | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- SALL3 | c.521C>A p.T174N | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SCAF1 | c.3167G>T p.S1056I | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- SCN4A | c.2501G>C p.G834A | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCN7A | c.2095G>A p.V699I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, varscan2
- SELE | c.802T>A p.C268S | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SELL | c.102G>C p.W34C (on ENST00000650983; = p.W21C on NM_000655.5) | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.014); called by muse, varscan2
- SELP | c.1163C>A p.P388Q | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.94); called by muse, mutect2
- SEMA5A | c.2285G>C p.G762A | Missense Mutation (SNP) | VAF 17/432 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.023); called by muse, mutect2
- SEMA5A | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 113/251 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SERPINA5 | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SERPINA9 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.416); called by muse, mutect2
- SERPINI2 | c.97C>A p.L33I | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.911); called by muse, varscan2
- SET | c.469C>T p.H157Y (on ENST00000372692 / NM_001374326.1; = p.H144Y on NM_003011.4) | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.208); called by muse, varscan2
- SETBP1 | c.2525T>A p.L842Q | Missense Mutation (SNP) | VAF 75/621 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SETBP1 | c.2982C>A p.Y994* | Nonsense Mutation (SNP) | VAF 61/528 reads (12%) | called by muse, mutect2, varscan2
- SH2B2 | c.287A>T p.D96V | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SI | c.4878G>T p.K1626N | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- SIK3 | c.1270C>A p.L424M (on ENST00000445177 / NM_001366686.2; = p.L430M on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/365 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- SIRPB1 | c.358T>G p.C120G | Missense Mutation (SNP) | VAF 46/684 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC10A3 | c.720C>A p.Y240* | Nonsense Mutation (SNP) | VAF 20/286 reads (7%) | called by muse, mutect2
- SLC38A11 | c.1128C>A p.C376* (on ENST00000409149 / NM_001351539.1; = p.C354* on NM_173512.2) | Nonsense Mutation (SNP) | VAF 36/150 reads (24%) | called by muse, varscan2
- SLC4A4 | c.2917G>A p.A973T (on ENST00000264485 / NM_001098484.3; = p.A929T on NM_003759.4) | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A17 | c.1951C>T p.L651F | Missense Mutation (SNP) | VAF 43/387 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- SLITRK2 | c.826A>T p.S276C | Missense Mutation (SNP) | VAF 51/376 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- SLITRK2 | c.890G>T p.R297M | Missense Mutation (SNP) | VAF 94/296 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLITRK2 | c.1372G>C p.V458L | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLITRK2 | c.1981G>T p.D661Y | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLITRK3 | c.2406G>C p.K802N | Missense Mutation (SNP) | VAF 66/320 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SLITRK3 | c.1834C>A p.P612T | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SMPD4 | c.762del p.S255Hfs*22 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- SNX18 | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.87); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SOBP | c.1306C>A p.P436T | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- SP110 | c.1258G>C p.A420P | Missense Mutation (SNP) | VAF 57/254 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- SPAG6 | c.1183G>T p.D395Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SPATA18 | c.1557A>T p.L519F | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- SPATA31D1 | c.437G>T p.W146L | Missense Mutation (SNP) | VAF 105/545 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTA1 | c.28G>T p.V10L | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- SRPRA | c.1247A>C p.Q416P | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SRRT | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 39/275 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- SS18 | c.1253A>T p.Q418L (on ENST00000415083 / NM_001007559.3; = p.Q387L on NM_005637.3) | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); called by muse, varscan2
- SSH1 | c.269G>T p.R90I | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1802G>T p.*601Lext*45 | Nonstop Mutation (SNP) | VAF 70/245 reads (29%) | called by muse, mutect2, varscan2
- ST6GALNAC5 | c.381del p.T128Hfs*14 | Frame Shift Del (DEL) | VAF 40/327 reads (12%) | called by mutect2, pindel, varscan2
- STARD8 | c.2408T>A p.L803Q | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- STIL | c.2384-1G>T p.X795_splice | Splice Site (SNP) | VAF 14/176 reads (8%) | called by muse, mutect2
- STK11IP | c.2745G>C p.W915C | Missense Mutation (SNP) | VAF 44/408 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.723); called by muse, mutect2
- STOML3 | c.197G>C p.G66A | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STRA6 | c.221G>C p.R74P | Missense Mutation (SNP) | VAF 112/413 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SVOP | c.1265G>A p.G422E | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SYCP1 | c.368C>G p.T123R | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- SYNE1 | c.7953G>T p.E2651D (on ENST00000367255 / NM_182961.4; = p.E2658D on NM_033071.3) | Missense Mutation (SNP) | VAF 88/326 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYT14 | c.593C>A p.P198Q | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- SYT4 | c.60C>G p.I20M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.088); called by muse, mutect2
- TACC2 | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF1L | c.1760C>A p.S587Y | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TANC2 | c.5810G>T p.R1937L | Missense Mutation (SNP) | VAF 88/417 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- TBRG1 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TBX5 | c.1227C>A p.S409R | Missense Mutation (SNP) | VAF 88/940 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.855); called by muse, mutect2
- TENM2 | c.6592A>G p.T2198A (on ENST00000518659 / NM_001122679.2; = p.T1959A on NM_001080428.3) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TEX37 | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 36/360 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TFB2M | c.582G>T p.M194I | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TFCP2L1 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 30/378 reads (8%) | called by muse, mutect2
- TIAM1 | c.4330G>T p.G1444W | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, varscan2
- TLNRD1 | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMC1 | c.1937T>A p.L646Q | Missense Mutation (SNP) | VAF 58/491 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TMEM132B | c.2809G>T p.G937C | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TMEM132C | c.2469C>A p.D823E | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- TMEM132D | c.458G>A p.G153D | Missense Mutation (SNP) | VAF 44/534 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM187 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 45/410 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TMEM187 | c.700G>C p.V234L | Missense Mutation (SNP) | VAF 39/408 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2
- TMEM239 | c.290G>T p.W97L (on ENST00000361033 / NM_001318207.1; = p.W54L on NM_001167670.3) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMTC1 | c.1819del p.T607Lfs*3 (on ENST00000539277 / NM_001193451.2; = p.T499Lfs*3 on NM_175861.3) | Frame Shift Del (DEL) | VAF 31/121 reads (26%) | called by mutect2, pindel, varscan2
- TOMM22 | c.14T>A p.V5D | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TOX3 | c.1279G>T p.A427S | Missense Mutation (SNP) | VAF 54/339 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM37 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 59/325 reads (18%) | called by muse, mutect2, varscan2
- TRIM42 | c.29C>A p.P10Q | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- TRIM58 | c.57C>A p.C19* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
- TRIML2 | c.955G>T p.G319C | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPA1 | c.944+1G>C p.X315_splice | Splice Site (SNP) | VAF 27/115 reads (23%) | called by muse, mutect2, varscan2
- TRPM3 | c.4976C>A p.S1659Y (on ENST00000357533 / NM_001366142.2; = p.S1514Y on NM_020952.6) | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TSHZ2 | c.2152T>A p.C718S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.23744A>T p.E7915V (on ENST00000591111; = p.E6988V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/123 reads (26%) | PolyPhen benign (0.122); called by muse, mutect2, varscan2
- U2SURP | c.1906A>G p.T636A | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE2O | c.2896G>A p.A966T | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBE2W | c.13C>A p.Q5K | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, varscan2
- UBE3C | c.1665dup p.I556Dfs*29 | Frame Shift Ins (INS) | VAF 61/218 reads (28%) | called by mutect2, pindel, varscan2
- UBQLNL | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- UNC5D | c.2847G>C p.R949S | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- UNC80 | c.3634G>T p.E1212* | Nonsense Mutation (SNP) | VAF 79/264 reads (30%) | called by muse, mutect2, varscan2
- UNK | c.2252G>T p.R751L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.129); called by mutect2, varscan2
- UPF3B | c.102del p.K35Rfs*16 | Frame Shift Del (DEL) | VAF 46/490 reads (9%) | called by mutect2, pindel
- UPK1A | c.236G>T p.S79I | Missense Mutation (SNP) | VAF 53/310 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- UPRT | c.679C>G p.P227A | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.561); called by muse, varscan2
- USH2A | c.3872C>A p.S1291Y | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); called by muse, mutect2
- USP34 | c.5244G>T p.K1748N | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- VAMP7 | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- VAV3 | c.2315C>A p.S772* | Nonsense Mutation (SNP) | VAF 12/74 reads (16%) | called by muse, varscan2
- VPS35 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- WARS1 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- XPO5 | c.3366G>C p.Q1122H | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZIM2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- ZMYM3 | c.3013C>G p.L1005V | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- ZNF138 | c.668A>G p.Y223C (on ENST00000307355 / NM_001367572.1; = p.Y197C on NM_006524.4) | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, varscan2
- ZNF160 | c.2113T>A p.Y705N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF37A | c.505A>G p.T169A | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF398 | c.1631G>T p.C544F (on ENST00000475153 / NM_170686.3; = p.C373F on NM_020781.4) | Missense Mutation (SNP) | VAF 155/479 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF460 | c.593G>T p.C198F | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF467 | c.883A>G p.T295A | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ZNF469 | c.546G>T p.R182S | Missense Mutation (SNP) | VAF 83/562 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- ZNF496 | c.1370A>T p.H457L | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF536 | c.2630C>T p.S877F | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by muse, mutect2
- ZNF577 | c.844A>G p.K282E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- ZNF605 | c.707G>T p.R236M | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ZNF609 | c.821C>G p.S274* | Nonsense Mutation (SNP) | VAF 64/261 reads (25%) | called by muse, mutect2, varscan2
- ZNF678 | c.62G>T p.S21I | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF717 | c.1871G>T p.C624F | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF735 | c.463A>G p.K155E | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2
- ZNF736 | c.226G>C p.A76P | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ZNF831 | c.2521G>T p.A841S | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ZXDA | c.600G>T p.Q200H | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ZYG11B | c.1025G>T p.R342L | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ABCA13 | c.5337T>C p.H1779= | Silent (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- ABCB7 | c.2067C>A p.T689= (on ENST00000373394 / NM_001271696.3; = p.T690= on NM_004299.6) | Silent (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- ADAMTSL3 | c.2244C>G p.P748= | Silent (SNP) | VAF 35/275 reads (13%) | called by muse, mutect2, varscan2
- ADGRE1 | c.1953C>A p.L651= | Silent (SNP) | VAF 55/177 reads (31%) | called by muse, mutect2, varscan2
- ADGRE3 | c.810G>T p.V270= | Silent (SNP) | VAF 53/175 reads (30%) | catalogued as COSV99505749; called by muse, mutect2, varscan2
- AL592490.1 | c.2109G>A p.E703= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as COSV69427732; called by muse, mutect2, varscan2
- AMOT | c.2214T>C p.N738= (on ENST00000371959 / NM_001113490.1; = p.N329= on NM_133265.3) | Silent (SNP) | VAF 30/295 reads (10%) | catalogued as COSV100495633; called by muse, mutect2, varscan2
- ANKDD1A | c.246C>A p.A82= | Silent (SNP) | VAF 43/161 reads (27%) | called by muse, mutect2, varscan2
- ANKIB1 | c.363A>G p.L121= | Silent (SNP) | VAF 85/270 reads (31%) | called by muse, mutect2, varscan2
- AP002512.3 | c.864C>A p.I288= | Silent (SNP) | VAF 29/106 reads (27%) | called by muse, mutect2, varscan2
- APOB | c.4014T>A p.P1338= | Silent (SNP) | VAF 30/240 reads (13%) | called by muse, mutect2, varscan2
- ARHGAP22 | c.1101A>T p.A367= | Silent (SNP) | VAF 90/251 reads (36%) | called by muse, mutect2, varscan2
- ASTN1 | c.3180T>A p.R1060= | Silent (SNP) | VAF 44/132 reads (33%) | called by muse, mutect2, varscan2
- B4GALNT4 | c.1428G>T p.P476= | Silent (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- BCL3 | c.1191A>G p.A397= | Silent (SNP) | VAF 86/403 reads (21%) | called by muse, mutect2, varscan2
- BGN | c.645C>A p.I215= | Silent (SNP) | VAF 30/358 reads (8%) | called by muse, mutect2
- BIRC6 | c.14352G>A p.K4784= | Silent (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- BTNL9 | c.342C>T p.G114= | Silent (SNP) | VAF 18/336 reads (5%) | called by muse, mutect2
- C16orf96 | c.1818C>T p.A606= | Silent (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- C18orf54 | c.60G>T p.L20= | Silent (SNP) | VAF 32/113 reads (28%) | called by muse, mutect2, varscan2
- C2orf16 | c.126G>A p.L42= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs758918197; called by muse, mutect2, varscan2
- CACNA1I | c.1137C>A p.I379= | Silent (SNP) | VAF 24/198 reads (12%) | catalogued as COSV60813863; called by muse, mutect2, varscan2
- CACNA1I | c.5800C>A p.R1934= | Silent (SNP) | VAF 24/171 reads (14%) | catalogued as COSV104414642; called by muse, mutect2, varscan2
- CADM2 | c.795C>G p.G265= (on ENST00000407528 / NM_001167674.2; = p.G267= on NM_153184.4) | Silent (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- CCKAR | c.1104C>A p.I368= | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as COSV55162149; called by muse, mutect2, varscan2
- CDH10 | c.1812C>A p.L604= | Silent (SNP) | VAF 46/748 reads (6%) | called by muse, mutect2
- CDH2 | c.1116G>C p.V372= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- CDH23 | c.6201C>T p.P2067= | Silent (SNP) | VAF 132/415 reads (32%) | catalogued as rs1405336719; called by muse, mutect2, varscan2
- CDH9 | c.2205G>T p.L735= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV50415600; called by muse, mutect2
- CDR1 | c.402G>A p.E134= | Silent (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- CELSR2 | c.225G>T p.A75= | Silent (SNP) | VAF 27/156 reads (17%) | called by muse, mutect2, varscan2
- CES4A | c.699A>T p.S233= | Silent (SNP) | VAF 29/226 reads (13%) | called by muse, mutect2, varscan2
- CFAP57 | c.1047A>T p.S349= | Silent (SNP) | VAF 88/338 reads (26%) | called by muse, mutect2, varscan2
- CLEC4C | c.285C>T p.Y95= | Silent (SNP) | VAF 8/135 reads (6%) | called by muse, mutect2
- COL19A1 | c.1116T>C p.P372= | Silent (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- COLEC11 | c.744G>T p.S248= | Silent (SNP) | VAF 186/737 reads (25%) | catalogued as COSV99362776, COSV99363003; called by muse, mutect2, varscan2
- CPXCR1 | c.345G>T p.G115= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV52163907; called by muse, mutect2, varscan2
- CRYBG1 | c.1626C>T p.P542= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs1175029919; called by muse, mutect2, varscan2
- CSMD3 | c.7923A>T p.G2641= (on ENST00000297405 / NM_001363185.1; = p.G2537= on NM_052900.3) | Silent (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- CSNK1D | c.432G>A p.L144= | Silent (SNP) | VAF 58/909 reads (6%) | called by muse, mutect2
- CT47B1 | c.657G>A p.A219= | Silent (SNP) | VAF 201/741 reads (27%) | catalogued as rs772976527, COSV64890339, COSV64890635; called by muse, mutect2, varscan2
- CTLA4 | c.22C>A p.R8= | Silent (SNP) | VAF 18/153 reads (12%) | called by muse, mutect2, varscan2
- CTSF | c.801G>T p.V267= | Silent (SNP) | VAF 72/244 reads (30%) | called by muse, mutect2, varscan2
- CYP2F1 | c.876A>T p.T292= | Silent (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- DAGLA | c.2605C>A p.R869= | Silent (SNP) | VAF 164/470 reads (35%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.666G>T p.G222= | Silent (SNP) | VAF 108/564 reads (19%) | called by muse, varscan2
- DCAF4L2 | c.324G>A p.T108= | Silent (SNP) | VAF 95/473 reads (20%) | catalogued as rs866937133, COSV60481476, COSV60482877; called by muse, mutect2, varscan2
- DNAH9 | c.11916G>A p.E3972= | Silent (SNP) | VAF 48/185 reads (26%) | called by muse, mutect2, varscan2
- EOMES | c.1221G>A p.E407= | Silent (SNP) | VAF 25/97 reads (26%) | called by muse, mutect2, varscan2
- EPHB1 | c.1065C>A p.T355= | Silent (SNP) | VAF 85/350 reads (24%) | catalogued as rs372552203; called by muse, mutect2, varscan2
- FAM131B | c.741G>T p.L247= | Silent (SNP) | VAF 77/643 reads (12%) | called by muse, mutect2, varscan2
- FAM135B | c.2955G>C p.V985= | Silent (SNP) | VAF 40/205 reads (20%) | called by muse, varscan2
- FAM135B | c.459G>T p.P153= | Silent (SNP) | VAF 40/518 reads (8%) | catalogued as COSV50525013; called by muse, mutect2
- FAM184B | c.555G>A p.S185= | Silent (SNP) | VAF 14/89 reads (16%) | called by muse, mutect2, varscan2
- FAM83E | c.612G>T p.G204= | Silent (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
- FBLN2 | c.1626C>T p.G542= | Silent (SNP) | VAF 87/266 reads (33%) | called by muse, mutect2, varscan2
- FFAR1 | c.240C>T p.P80= | Silent (SNP) | VAF 23/206 reads (11%) | catalogued as COSV50049907; called by muse, mutect2, varscan2
- FOXL1 | c.984C>A p.P328= | Silent (SNP) | VAF 25/182 reads (14%) | catalogued as rs1457402520; called by muse, mutect2, varscan2
- GABRB3 | c.87G>T p.G29= | Silent (SNP) | VAF 38/404 reads (9%) | called by muse, mutect2
- GHR | c.1821C>A p.L607= | Silent (SNP) | VAF 34/315 reads (11%) | called by muse, mutect2, varscan2
- GPSM2 | c.1614T>C p.P538= | Silent (SNP) | VAF 33/262 reads (13%) | called by muse, mutect2, varscan2
- HCFC1 | c.4171C>T p.L1391= | Silent (SNP) | VAF 25/207 reads (12%) | called by muse, mutect2, varscan2
- HDGFL1 | c.552G>T p.A184= | Silent (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- HEATR1 | c.564C>T p.F188= | Silent (SNP) | VAF 9/144 reads (6%) | catalogued as COSV63979362; called by muse, mutect2
- HECTD4 | c.11301C>T p.T3767= | Silent (SNP) | VAF 29/233 reads (12%) | called by muse, mutect2, varscan2
- HMCN2 | c.657G>A p.L219= | Silent (SNP) | VAF 44/157 reads (28%) | called by muse, mutect2, varscan2
- HOXB7 | c.378C>A p.I126= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- IGKV2-28 | c.219C>A p.I73= | Silent (SNP) | VAF 24/224 reads (11%) | called by muse, mutect2, varscan2
- IL18RAP | c.423C>T p.V141= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- IL2RA | c.30G>C p.L10= | Silent (SNP) | VAF 22/332 reads (7%) | catalogued as COSV56923563; called by muse, mutect2
- IPO8 | c.1506G>T p.A502= | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- KCNK16 | c.570C>A p.V190= | Silent (SNP) | VAF 79/225 reads (35%) | called by muse, mutect2, varscan2
- KCTD17 | c.336C>G p.A112= | Silent (SNP) | VAF 21/146 reads (14%) | catalogued as COSV63249053; called by muse, mutect2, varscan2
- KDM4D | c.1317A>G p.P439= | Silent (SNP) | VAF 85/308 reads (28%) | called by muse, mutect2, varscan2
- KIAA1549L | c.3006G>A p.V1002= (on ENST00000321505; = p.V1299= on NM_012194.3) | Silent (SNP) | VAF 55/343 reads (16%) | called by muse, mutect2, varscan2
- KIF26A | c.2715A>T p.P905= | Silent (SNP) | VAF 20/114 reads (18%) | called by muse, mutect2, varscan2
- KIF26A | c.4101G>T p.R1367= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as rs759549209; called by muse, mutect2, varscan2
- KLHDC9 | c.780G>A p.R260= | Silent (SNP) | VAF 76/648 reads (12%) | catalogued as COSV63509638; called by muse, mutect2, varscan2
- KLK1 | c.483C>A p.I161= | Silent (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- KRT5 | c.1644G>T p.V548= | Silent (SNP) | VAF 129/392 reads (33%) | catalogued as rs141330791; called by muse, mutect2
- KRT76 | c.1362A>G p.L454= | Silent (SNP) | VAF 139/514 reads (27%) | called by muse, mutect2, varscan2
- KRTAP16-1 | c.804G>T p.T268= | Silent (SNP) | VAF 94/490 reads (19%) | called by muse, mutect2, varscan2
- L3MBTL1 | c.261G>T p.L87= (on ENST00000418998 / NM_001377303.1; = p.L65= on NM_032107.5) | Silent (SNP) | VAF 179/626 reads (29%) | called by muse, mutect2, varscan2
- LAMA3 | c.6828A>T p.I2276= (on ENST00000313654 / NM_198129.4; = p.I667= on NM_000227.6) | Silent (SNP) | VAF 83/383 reads (22%) | called by muse, mutect2, varscan2
- LILRB2 | c.808C>A p.R270= | Silent (SNP) | VAF 93/466 reads (20%) | called by muse, varscan2
- LILRB2 | c.807C>A p.G269= | Silent (SNP) | VAF 94/462 reads (20%) | called by muse, varscan2
- LRRTM4 | c.126C>T p.G42= | Silent (SNP) | VAF 10/159 reads (6%) | called by muse, mutect2
- MAGEH1 | c.165G>A p.P55= | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as COSV61678730; called by muse, mutect2, varscan2
- MED12L | c.5160C>A p.P1720= | Silent (SNP) | VAF 81/339 reads (24%) | catalogued as COSV56400212; called by muse, mutect2, varscan2
225 further variants in this file (0 protein-altering or splice-affecting, 100 silent, 125 other) are not listed here.
